Somatic mutation profile of tumor specimen TCGA-EJ-5517-01A (aliquot TCGA-EJ-5517-01A-01D-1576-08) from TCGA case TCGA-EJ-5517, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,422 days).
Specimen TCGA-EJ-5517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3966594-85ed-4128-abd6-6892ab88a776.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5517-10A (Blood Derived Normal), aliquot TCGA-EJ-5517-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/726c6a05-43b5-4945-b651-2108ffda035a

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIM2 | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 190/585 reads (32%) | catalogued as rs752653022, COSV63698332; called by mutect2, pindel, varscan2
- EPC2 | c.1145T>G p.L382W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV51542824; called by muse, varscan2
- FOXA3 | c.426A>T p.E142D | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56215477; called by muse, mutect2
- KRT6C | c.1133A>T p.K378M | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52877304; called by muse, mutect2
- PASK | c.577G>C p.A193P | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52151261, COSV99300480; called by muse, mutect2, varscan2
- PCDHGB7 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV53929042; called by muse, mutect2, varscan2
- PSRC1 | c.748G>A p.V250I (on ENST00000409138 / NM_001363309.1; = p.V220I on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.093); catalogued as rs567496428, COSV64021185; called by muse, mutect2, varscan2
- PUM2 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.06); catalogued as rs779561678, COSV57579727; called by muse, mutect2
- RTL8C | c.280T>A p.Y94N | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57059988; called by muse, mutect2, varscan2
- TAF1D | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768692948, COSV100127006, COSV58680005; called by muse, mutect2, varscan2
- TNXB | c.9926G>A p.R3309H (on ENST00000647633; = p.R3062H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs769949134, COSV64477245; called by muse, mutect2, varscan2
- TRAF3IP3 | c.803T>A p.V268E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV50552046; called by muse, mutect2, varscan2
- ULK4 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs756225801, COSV57205323; called by muse, mutect2, varscan2
- ZBTB3 | c.1293C>G p.F431L | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67360816, COSV67360821; called by muse, mutect2, varscan2
- BIN1 | c.373_378delinsT p.T125* | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | called by pindel, varscan2*
- GSK3B | c.633del p.E211Dfs*17 | Frame Shift Del (DEL) | VAF 28/168 reads (17%) | called by mutect2, pindel, varscan2
- TPR | c.4211del p.N1404Ifs*3 | Frame Shift Del (DEL) | VAF 24/212 reads (11%) | called by mutect2, pindel, varscan2
- DAAM2 | c.252G>A p.K84= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1239546258, COSV51308974; called by muse, mutect2, varscan2
- DPP6 | c.1923C>T p.F641= (on ENST00000377770 / NM_001364500.2; = p.F579= on NM_001936.5) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs745857465, COSV59603650; called by muse, mutect2
- PCDHB8 | c.447T>A p.P149= | Silent (SNP) | VAF 91/516 reads (18%) | catalogued as COSV50761722; called by muse, mutect2, varscan2
- TPCN1 | c.2418A>T p.P806= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV52527339; called by muse, mutect2, varscan2
- USP9X | c.1128G>A p.E376= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV61068132; called by muse, mutect2, varscan2
- ZNF534 | c.75G>A p.L25= | Silent (SNP) | VAF 60/183 reads (33%) | catalogued as COSV56516207; called by muse, mutect2, varscan2
- DCHS2 | n.3047G>A | RNA (SNP) | VAF 33/408 reads (8%) | catalogued as rs1049144150, COSV59718522; called by muse, mutect2
